Somatic mutation profile of tumor specimen MP2PRT-PARFTF-TMP1-A (aliquot MP2PRT-PARFTF-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARFTF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,185 days).
Specimen MP2PRT-PARFTF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4323a4f7-114c-4146-8b9e-4f33d37f32f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARFTF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARFTF-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/233fc7b2-c011-4ac8-af64-023c0559d6ed

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS6 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.934); catalogued as rs957597714; called by muse, mutect2
- KCNQ1 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 251/523 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); catalogued as rs866169644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPS15 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 190/447 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776496972, COSV64152121; called by muse, mutect2, varscan2
- OR6A2 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 141/386 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60264727; called by muse, mutect2, varscan2
- TIAM1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 35/724 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.41); catalogued as rs142771097, COSV54544619, COSV54557887; called by muse, mutect2
- UNC80 | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 69/569 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs374867757; called by muse, mutect2, varscan2
- COL4A5 | c.4916A>T p.N1639I | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUL4A | c.2271_2272insCC p.V758Pfs*13 (on ENST00000375440 / NM_001008895.4; = p.V658Pfs*13 on NM_003589.3) | Frame Shift Ins (INS) | VAF 59/199 reads (30%) | called by mutect2, varscan2
- INTS2 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- YTHDF2 | c.1662dup p.D555* | Frame Shift Ins (INS) | VAF 56/124 reads (45%) | called by mutect2, varscan2
- SCN1A | c.2271G>A p.V757= (on ENST00000303395 / NM_001202435.3; = p.V746= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/125 reads (53%) | called by muse, mutect2, varscan2
